Somatic mutation profile of tumor specimen TCGA-CQ-A4C7-01A (aliquot TCGA-CQ-A4C7-01A-11D-A25D-08) from TCGA case TCGA-CQ-A4C7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 88.1 years (32,194 days).
Specimen TCGA-CQ-A4C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80db5a37-eea4-4936-8cd1-575d8c999684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4C7-10A (Blood Derived Normal), aliquot TCGA-CQ-A4C7-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aabc606-284f-401f-850b-adc165979f97

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2 | c.3542A>G p.D1181G | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99970216; called by muse, mutect2, varscan2
- AMIGO2 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV99873854; called by muse, mutect2, varscan2
- ANKAR | c.2362C>G p.L788V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99854846; called by muse, mutect2
- B4GALT6 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV52702565; called by muse, mutect2
- BOD1L1 | c.7654C>T p.L2552F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); catalogued as COSV99240651; called by muse, mutect2
- CASZ1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as COSV100682365; called by muse, mutect2, varscan2
- CLEC14A | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100643704; called by muse, mutect2, varscan2
- COL9A1 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs547618159, COSV57888307; called by muse, mutect2, varscan2
- CPNE3 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99548270; called by muse, mutect2
- CRH | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as rs767889647, COSV99396358; called by muse, mutect2, varscan2
- CTNNA3 | c.1914C>A p.D638E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.983); catalogued as rs954219089, COSV101052187, COSV65583498; called by muse, mutect2, varscan2
- DCLRE1C | c.1879G>A p.E627K (on ENST00000378278 / NM_001350965.2; = p.E512K on NM_022487.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.014); catalogued as COSV57953116; called by muse, mutect2, varscan2
- DNMT3L | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as rs368058982, COSV99533324; called by muse, mutect2, varscan2
- DST | c.3596A>C p.E1199A (on ENST00000361203 / NM_001374722.1; = p.E873A on NM_001723.6) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs1245295401, COSV99761231; called by muse, mutect2, varscan2
- EPRS1 | c.2519T>G p.L840R | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100859557; called by muse, mutect2, varscan2
- FBLN5 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747288805, COSV99970079; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- GMNN | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV57776638; called by muse, mutect2, varscan2
- GRIN2A | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411491, COSV58061070; called by muse, mutect2
- LAMA3 | c.8452G>A p.V2818I (on ENST00000313654 / NM_198129.4; = p.V1209I on NM_000227.6) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV99336098; called by muse, mutect2, varscan2
- LPA | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs375355500; called by muse, mutect2
- N4BP2 | c.2275A>G p.R759G | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV99788146, COSV99789441; called by muse, mutect2, varscan2
- NBAS | c.6181C>A p.P2061T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99872179; called by muse, mutect2, varscan2
- NLRP5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs770891485, COSV66764352; called by muse, mutect2, varscan2
- OR13F1 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100594898; called by muse, mutect2, varscan2
- OR5T3 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100282988; called by muse, mutect2
- PGC | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV100729770; called by muse, mutect2
- PHF20L1 | c.1433G>C p.S478T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99622428; called by muse, mutect2
- PRR14 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV99788682; called by muse, mutect2
- PTPRZ1 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV101100983; called by muse, mutect2, varscan2
- RABGGTA | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs751373180, COSV99253326; called by muse, varscan2
- RCOR2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV56851371; called by muse, mutect2, varscan2
- RNF113B | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99940459; called by muse, mutect2, varscan2
- SEMA5B | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99533584; called by muse, mutect2, varscan2
- SH3KBP1 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV101116526; called by muse, mutect2, varscan2
- SLC30A2 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100958649, COSV65332633; called by muse, mutect2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TRAT1 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99849677; called by muse, mutect2, varscan2
- TSLP | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100789233; called by muse, mutect2
- TTC17 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99236360; called by muse, mutect2
- UNC45B | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV99269469; called by muse, mutect2, varscan2
- WNK3 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100672363; called by muse, mutect2, varscan2
- ZBTB49 | c.1773G>T p.E591D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100552371, COSV100552656; called by muse, mutect2, varscan2
- ZNF91 | c.2714C>G p.T905S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV100323652; called by muse, mutect2, varscan2
- AFTPH | c.283_285del p.E95del | In Frame Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- DACH1 | c.1931A>T p.Q644L (on ENST00000619232 / NM_001366712.1; = p.Q390L on NM_004392.6) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.442); called by muse, mutect2
- MAS1 | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2
- ADGRL2 | c.198G>T p.R66= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV99592168; called by muse, mutect2
- BEST4 | c.750C>A p.L250= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- CCDC77 | c.1215C>T p.R405= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs531003434, COSV99520127; called by mutect2, varscan2
- CHRNA1 | c.1020C>A p.V340= (on ENST00000261007 / NM_001039523.3; = p.V315= on NM_000079.4) | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99650820; called by muse, mutect2, varscan2
- DRAP1 | c.99G>A p.A33= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV56988282; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.360C>G p.P120= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV99955538, COSV99955639; called by muse, mutect2
- ENAM | c.1419G>A p.L473= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101253408; called by muse, mutect2, varscan2
- GIGYF1 | c.684C>T p.S228= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs780018581, COSV99308740, COSV99310214; called by muse, mutect2, varscan2
- ITPK1 | c.156C>T p.P52= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99969165; called by muse, mutect2, varscan2
- KCNA4 | c.1230C>G p.V410= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100069354; called by muse, mutect2
- LYPD6B | c.90T>C p.V30= (on ENST00000409029 / NM_001317004.1; = p.V54= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as COSV99700586; called by muse, mutect2, varscan2
- NELL2 | c.1872C>T p.G624= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs201592050; called by muse, mutect2, varscan2
- PCDH11X | c.2994G>A p.V998= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100016409, COSV53509205; called by muse, mutect2, varscan2
- RPL5 | c.354C>T p.I118= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV59874433; called by muse, mutect2
- SHISAL1 | c.123C>T p.Y41= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV101152141; called by muse, mutect2
- ZNF33A | c.207G>A p.E69= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs1328860184, COSV100276319; called by muse, mutect2
- ZNF417 | c.1542T>C p.H514= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100364472; called by muse, mutect2, varscan2
